Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A895, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A895-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, papillary renal cell
8260/3
Site (R) Kidney NOS C64.9
gt 11/22/13

Research Gross Description

male with right renal mass

Research Dx

Kidney, right, robotic assisted laparoscopic partial nephrectomy:

Papillary renal cell carcinoma, multifocal (at least 6 tumors).

Please see case summary and comment.

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: robotic-assisted laparoscopic partial nephrectomy

Specimen laterality: right

Tumor site: lower pole

Tumor size:

#1 largest: 6.0 cm

#2-#6: 0.3 cm, 0.3 cm, 0.1 cm, 0.1 cm, <0.1 cm

Tumor focality: multifocal

Macroscopic extent of tumor: tumors limited to kidney

Histologic type: papillary renal cell carcinoma (largest is type 1)

Sarcomatoid features: not identified

Tumor necrosis: not identified

Histologic grade (Fuhrman Nuclear Grade): grade 2

Microscopic tumor extension: tumors limited to kidney

Margins: negative for invasive carcinoma:

___ Renal parenchymal margin: negative (closest 1mm tumor is 1 mm from margin)

___ Renal capsular margin: negative

___ Perinephric fat margin: negative

Lymphovascular invasion: not identified

Pathologic staging (pTNM):

TNM descriptors: m, multiple primary tumors

Primary tumor: pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

Regional lymph nodes: pNx: Regional lymph nodes cannot be assessed (tissue in A submitted as a lymph node has no lymph node)

Number examined: 0

Number involved: 0

Distant metastasis: pM not applicable

Pathologic findings in nonneoplastic kidney: hypercellular, enlarged glomeruli, globally sclerotic glomeruli, arteriolonephrosclerosis, interstitial fibrosis and chronic inflammation

Other tumors and/or tumor-like lesions: multiple smaller papillary renal cell carcinomas (as described above)

AJCC Staging (7th edition) pT1b(m) pNx pM not applicable

Research QC

Tumor:

100% tumor nuclei

0% necrosis

0% normal

Normal:

[page 2 of 2]
100% kidney

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time:

Formalin fixation stop time

Total formalin fixation time

Specimen Weight

Normal

1- 395 mg, 2- 381 mg, 3- 233 mg, 4- 385 mg

Tumor

1- 398 mg, 2- 422 mg, 3- 320 mg, 4- 294 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 8

Normal x 4

Tumor x 4

Metastatic x 0

FFPE x 8

Normal x 4

Tumor x 4

Metastatic x 0

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 177fd781-869f-40b5-b122-a8b4292fb754 (TCGA-Y8-A895.29F6869E-B06D-45DD-898D-8CEF187D0F53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).